Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7367, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7367-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Accession Number: [REDACTED]

Final Report

DIAGNOSIS:

- 1) MARGIN, LEFT ANTERIOR TONGUE, EXCISION: NEGATIVE FOR MALIGNANCY.
- 2) MARGIN, LEFT BASE OF TONGUE, EXCISION: NEGATIVE FOR MALIGNANCY.
- 3) MANDIBLE, TONGUE, SUPERIOR NECK, RADICAL RESECTION: INVASIVE WELL-DIFFERENTIATED KERATINIZING SQUAMOUS CELL CARCINOMA, 8.5 CM IN GREATEST EXTENT, INVOLVING THE SKIN AND FLOOR OF MOUTH WITH EROSION INTO THE MANDIBLE AND MUCOSAL ULCERATION; PERINEURAL INVASION PRESENT, NEGATIVE FOR DEFINITIVE LYMPHOVASCULAR INVASION; TONSIL UNINVOLVED; TUMOR EXTENDS TO LESS THAN 0.1 CM FROM THE SUPERIOR LATERAL RESECTION MARGIN; HOWEVER, ALL INKED RESECTION MARGINS NEGATIVE FOR TUMOR (SEE COMMENT).
- 4) LYMPH NODE, LEVEL 2 POSTERIOR, EXCISION: 7 LYMPH NODES, NEGATIVE FOR MALIGNANCY.
- 5) LYMPH NODE, LEFT NECK LEVEL 2,3 EXCISION: 1 OF 6 LYMPH NODES INVOLVED BY SQUAMOUS CELL CARCINOMA, MICROSCOPIC FOCUS PRESENT WITHIN A 1.5 CM LYMPH NODE (NEGATIVE FOR EXTRANODAL EXTENSION).
- 6) LYMPH NODE, LEFT LEVEL 4, EXCISION: 8 LYMPH NODES, NEGATIVE FOR MALIGNANCY.
- 7) LYMPH NODE, POSTERIOR LEVEL 3, EXCISION: 7 LYMPH NODES, NEGATIVE FOR MALIGNANCY.
- 8) LYMPH NODE, LEFT NECK LEVEL 4, EXCISION: 2 LYMPH NODES, NEGATIVE FOR MALIGNANCY.

COMMENT: These findings correspond to AJCC 6th edition pathologic stage I V A (pT4aN1M n/a).

Electronically signed by: [REDACTED]

CLINICAL DATA

Clinical Features/Dx: unspecified

[page 2 of 4]
Operator: [REDACTED]
Operation: unspecified
Operative Findings: unspecified
Operative Diagnosis: unspecified
Tissue Submitted: 1) left anterior tongue margin, 2) left base of tongue margin, 3) left composite jaw-neck-tongue, 4) level 2 posterior, 5) left neck levels 2-3, 6) left neck level 4, 7) posterior level 3, 8) left neck level 4 lymph nodes

GROSS DESCRIPTION:

1) SOURCE: Left Anterior Tongue Margin

The specimen labeled, "left anterior tongue margin," is received fresh and is comprised of a 0.2 x 0.1 x 0.1 cm piece of mucosal tissue. The specimen is entirely submitted for frozen section.

Summary of sections: 1AFSC, entirely submitted, 1/1.

2) SOURCE: Left Base of Tongue Margin

The specimen labeled, "left base of tongue margin," is received fresh and is comprised of a 2.8 x 1.0 x 0.4 cm strip of mucosal tissue with underlying soft tissues. The specimen is submitted entirely for frozen section.

Summary of sections: 2AFSC, entirely submitted, 1/1.

3) SOURCE: Left Composite, Jaw-Neck-Tongue

The specimen labeled, "left composite resection, tongue, jaw, neck," is received fresh and is comprised of a mandibular resection extending from the right mandible anterior to the mental foramen, to the left angle of the mandible. Attached is the base of the tongue, floor of mouth, and a significant portion of soft tissue from the left anterior lateral chin/superior neck. The left tonsil is attached. The specimen measures 11.0 cm superficial to deep (anterior to posterior), 10.0 cm superior to inferior, and 6.5 cm medial to lateral. The overlying skin is pink-tan, hair-bearing, and possesses an ulcerated mass, measuring 8.5 x 5.8 surface centimeters. The specimen is inked as follows on the resection surfaces: anterior-yellow, posterior-green, superior-red, inferior-black, lateral-blue, medial-orange. The left palatal tonsil is present attached to the specimen, and measures 2.6 x 1.3 x 2.2 cm. The specimen is sectioned to show the mass lesion extending deep into the specimen to a depth of 5.5 cm and is comprised of a soft, white-tan parenchyma with an infiltrative border. This process surrounds and apparently invades the mandibular bone. The process comes within 0.3 cm of the lateral superior resection margin (blue). The tonsil is appears free of this process. A portion of the tumor is retained for research purposes. Representative tumor is retained in RPMI, glutaraldehyde, and frozen at -80 degrees for possible future studies. Representative sections are submitted. Appropriate sections are decalcified.

Summary of sections: 3A, anterior medial bony margin en face, 1/1; 3B, posterior bony margin en face, 1/1; 3C, lateral margin, 2/1; 3D,

[page 3 of 4]
inferior margin, 1/1; 3E, inferior margin, 1/1; 3F, deep margin, 2/1; 3G, medial margin, 2/1; 3H, superior margin, 1/1; 3I, tonsillar margin, 1/1; 3J, anterior (superficial) margin, 2/1; 3K, possible hypoglossal nerve margin versus tendon, 1/1; 3L, floor of mouth (red ink in floor of mouth is not true margin, red ink on tongue muscle is true margin), 1/1; 3M-N, mandibular involvement, 2/2; 3O, skin, 1/1; 3P, tonsil, 1/1; 3Q, representative sections, 2/1.

4) SOURCE: Level 2 Posterior

Received fresh is a 3.5 x 2.5 x 1.3 cm portion of partially circumscribed, yellow-tan, lobular, adipose tissue with a nodularity noted on palpation. The dissected lymph nodes range in size from 0.4 cm up to the largest, 1.1 cm in greatest length. The lymph nodes are submitted in total.

Summary of sections: 4A, two lymph nodes, each bisected, 4/1; 4B, three lymph nodes, one bisected, 4/1.

5) SOURCE: Left Neck Level 2, 3

Received fresh labeled, "left neck level 2, 3," is a 4.5 x 2.5 x 1.8 cm portion of yellow-tan fibrofatty tissue, with a nodularity noted on palpation. The specimen is dissected for lymph nodes. The dissected lymph nodes range in size from 1.4 cm in greatest dimension up to 3.0 cm in greatest dimension. The lymph nodes are submitted entirely.

Summary of sections: 5A, two lymph nodes, each bisected, 4/1; 5B, one lymph node, bisected, 2/1; 5C-D, one lymph node, bisected, 1/1 each.

6) SOURCE: Left Level 4

Received fresh labeled, "left level 4," is a 5.0 x 4.0 x 1.4 cm portion of partially circumscribed, yellow-gray, fibrofatty tissue, with a nodularity noted on palpation. The dissected lymph nodes range from 0.3 cm up to the largest, 1.4 cm in greatest dimension. The lymph nodes are submitted.

Summary of sections: 6A, three lymph nodes, two bisected, 5/1; 6B, three lymph nodes, two bisected, 5/1; 6C, four lymph nodes, 4/1.

7) SOURCE: Posterior Level 3

Received fresh labeled, "posterior level 3," is a 3.0 x 3.0 x 1.2 cm portion of partially circumscribed, yellow-tan, lobular, fibrofatty tissue, with a nodularity noted on palpation. The dissected lymph nodes range in size from 0.3 to 0.6 cm in greatest dimension. The lymph nodes are submitted.

Summary of sections: 7A, four lymph nodes, 4/1; 7B, three lymph nodes, 3/1.

8) SOURCE: Left Neck Level 4 Lymph node

Received fresh labeled, "left neck level 4 lymph node," is a 3.5 x 2.0 x 1.2 cm portion of partially circumscribed, yellow-tan, lobular, adipose tissue, with a nodularity noted on palpation. Serial sectioning shows a red-brown cut surface, grossly consistent with a portion of muscle, and

[page 4 of 4]
a single lymph node, 2.0 x 1.2 x 1.0 cm. The lymph node is bisected and submitted in total.

Summary of sections: 8A, 2/1.

Dictated by [redacted] 2.
Dictated by [redacted]
[redacted]
Dictated by [redacted]
Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Left Anterior Tongue Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [redacted]

2) SOURCE: Left Base of Tongue Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [redacted]

Electronically signed by: [redacted]

The following special studies were performed on this case and the interpretation is incorporated in the diagnostic report above:
1xDECALCIFICATION
SNOMED: T-51000,T-51000,M-80703,

Source: NCI Genomic Data Commons file a50c6768-f9fc-4d8f-9a33-ec56cdfa6dce (TCGA-CR-7367.5353C2CD-AA3E-4D76-9AA5-8609310C904D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).